Somatic mutation profile of tumor specimen MP2PRT-PARIHP-TMP1-A (aliquot MP2PRT-PARIHP-TMP1-A-1-0-D-A834-36) from MP2PRT case MP2PRT-PARIHP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,330 days).
Specimen MP2PRT-PARIHP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9da9d269-abe9-465a-8731-8f5e82a65084.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARIHP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARIHP-NB1-A-1-0-D-A834-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6189bedb-d79b-4318-b82c-f4c9d34e878c

The open-access MAF lists 15 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Frame Shift Ins 1, Intron 1, Silent 1, In Frame Del 1, In Frame Ins 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 75/307 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/306 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- GPT | c.652G>A p.V218M | Missense Mutation (SNP) | VAF 225/708 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.134); catalogued as rs1374268857; called by muse, varscan2
- PDZRN3 | c.2687C>T p.A896V | Missense Mutation (SNP) | VAF 98/414 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs560009760, COSV55203300; called by muse, mutect2, varscan2
- ABCA7 | c.2051_2067+1del | In Frame Del (DEL) | VAF 3/26 reads (12%) | called by mutect2*, pindel
- C1GALT1C1L | c.677delinsCCC p.Y226Sfs*39 | Frame Shift Ins (INS) | VAF 20/30 reads (67%) | called by pindel, varscan2*
- ITPRID1 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 137/315 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- LRCH2 | c.983A>T p.Q328L | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PEG3 | c.4289_4290insTGCAGAGCCCATTGGAGAGGCTGGACAGCCAAATGGAGAGGC p.A1430_E1431insAEPIGEAGQPNGEA | In Frame Ins (INS) | VAF 3/27 reads (11%) | called by mutect2*, pindel
- POLR3D | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 112/750 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.324); called by muse, varscan2
- TENM1 | c.2899C>G p.Q967E | Missense Mutation (SNP) | VAF 64/521 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TTN | c.22310A>T p.H7437L (on ENST00000591111; = p.H6510L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/241 reads (11%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- SHANK2 | c.3615C>T p.L1205= | Silent (SNP) | VAF 44/432 reads (10%) | called by muse, varscan2
- MCF2 | c.*29C>G | 3'UTR (SNP) | VAF 93/373 reads (25%) | called by muse, mutect2, varscan2
- TTN | c.34264+5293G>A | Intron (SNP) | VAF 103/261 reads (39%) | catalogued as rs1209026573, COSV60114890, COSV60160537; ClinVar: likely benign; called by muse, varscan2
